EXCEPTIONAL_RESPONDERS case ER-ABDN — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b5cdec9-b67f-452e-b4da-af8d752b7334

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive.

Diagnoses (1)
1. Hepatoid adenocarcinoma: ICD-O-3 morphology code: 8576/3; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Cardia, NOS; Age at diagnosis: 54.4 years (19,872 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 713 days (2.0 years); Days to best overall response: 91 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 13 days; Days to treatment end: 851 days (2.3 years).
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 13 days; Days to treatment end: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 13 days; Days to treatment end: 839 days (2.3 years).

Follow-up (1 entry)
- Days to follow up: 713 days (2.0 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 713 days (2.0 years); Days to recurrence: 713 days (2.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABDN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABDN-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
